Gene-level copy-number profile of tumor specimen ALCH-B058-TTP1-A from ALCHEMIST case ALCH-B058, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 76.4 years (27,914 days).
Specimen ALCH-B058-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e17257cd-da3c-4a1e-b9dd-791e9bb5a4bd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B058-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/c3cd878f-8583-4b08-8587-38029b3bbaa5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 513; copy number 1: 4,308; copy number 2: 49,471; copy number 3: 3,552; copy number 4: 988; copy number 5: 31; copy number 6: 39.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:188,159,705–188,161,157, 1 gene: LINC02434.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 70 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:101,962,056–102,736,888, 16 genes, copy number 6: LINC01127, IL1R2, IL1R1, IL1R1-AS1, IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2, MFSD9.
- chr3:187,796,187–190,659,750, 28 genes, copy number 5 (within-gene range 4–5): AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3.
- chr9:41,340,823–41,355,538, 1 gene, copy number 5: CDRT15P6.
- chr11:35,132,655–35,232,402, 2 genes, copy number 5 (within-gene range 3–5): AL356215.1, CD44.
- chr20:1,023,874–1,620,061, 23 genes, copy number 6: AL110114.1, PSMF1, ACTG1P3, TMEM74B, AL031665.1, C20orf202, RAD21L1, SNPH, SDCBP2, AL136531.2, AL136531.3, SDCBP2-AS1, AL136531.1, FKBP1A, MIR6869, NSFL1C, SIRPB2, AL049634.1, RNU6-917P, SIRPD, AL049634.2, SIRPB1, AL049634.3.

Autosomal genes at a single copy (total copy number 1): 1,964. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
